Gene-level copy-number profile of tumor specimen TCGA-AA-A02F-01A from TCGA case TCGA-AA-A02F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.6 years (25,051 days).
Specimen TCGA-AA-A02F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.cce9277a-fd51-403b-9a58-91e324c8a3a9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c09dee48-df73-49a2-9b1b-57e1a67ad0d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 556; copy number 1: 18,356; copy number 2: 36,103; copy number 3: 4,959; copy number 4: 264; copy number 5: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02F-01A-01D-A008-01): tumor purity 0.94, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:114,827,763–115,113,876, 1 gene (within-gene range 0–1): NDST4.
- chr10:87,751,512–88,877,544, 23 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2.
- chr16:6,748,908–6,748,969, 1 gene: RNU7-99P.
- chr16:7,431,217–7,431,296, 1 gene: AC007222.1.
- chr19:42,752,686–42,855,691, 1 gene (within-gene range 0–2): PSG8.
- chr19:42,821,863–42,950,387, 6 genes: PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7.
- chr19:43,007,656–43,041,248, 2 genes: PSG11, CEACAMP8.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–1,101,400, 20 genes, copy number 5 (within-gene range 2–5): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2.

Autosomal genes at a single copy (total copy number 1): 15,935. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
